Gene-level copy-number profile of tumor specimen ALCH-ADGG-TTP1-A from ALCHEMIST case ALCH-ADGG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,045 days).
Specimen ALCH-ADGG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2bcd5f06-460b-4a14-a803-47b9c22eb305.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADGG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/af0caad0-dc54-46b2-b04d-95df07cc24a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 14,774; copy number 2: 41,942; copy number 3: 2,120; copy number 4: 23; copy number 5: 24; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:109,326,141–109,364,234, 2 genes: DPPA4, AC124945.1.
- chr6:73,209,746–73,310,365, 6 genes (within-gene range 0–1): AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1.
- chr8:33,591,330–33,600,023, 1 gene: DUSP26.
- chr8:33,641,581–33,641,939, 1 gene (within-gene range 0–1): BUD31P1.
- chr13:19,674,752–19,783,019, 2 genes (within-gene range 0–1): PSPC1, RN7SL166P.
- chr14:34,675,891–34,675,994, 1 gene: RNU6-1261P.
- chr16:18,533,418–18,533,817, 1 gene: AC136618.2.
- chr16:21,879,338–21,919,156, 1 gene (within-gene range 0–2): SMG1P4.
- chr17:439,978–445,939, 1 gene: RFLNB.
- chr17:3,601,761–3,602,272, 1 gene (within-gene range 0–1): AC027796.1.
- chr22:18,029,385–18,037,968, 1 gene: LINC01634.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,156,329–26,219,240, 16 genes, copy number 5: H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P.
- chr6:32,549,940–32,706,955, 7 genes, copy number 5: RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1.
- chr10:38,783,004–38,783,108, 1 gene, copy number 6: AL590623.1.
- chr21:38,805,183–38,824,955, 1 gene, copy number 5: ETS2.

Autosomal genes at a single copy (total copy number 1): 11,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
